Surgical pathology report (de-identified scan), TCGA case TCGA-C5-A2LY, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Medical College of Wisconsin, specimen TCGA-C5-A2LY-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Patient Name: _____

Address: _____

Gender: F

DOB: _____

Service: Gynecology

Location: OTHER

MRN: _____

Hospital #: _____

Patient Type: _____

Accession #: _____

Taken: _____

Received: _____

Reported: _____

Physician(s): _____

M.D.

DIAGNOSIS:

UTERUS, CERVIX, BIOPSY

- SQUAMOUS CELL CARCINOMA, MODERATELY DIFFERENTIATED, INVASIVE

LYMPH NODE, "RIGHT EXTERNAL," DISSECTION

- NO EVIDENCE OF MALIGNANCY (2/2)

- ENDOSALPINGIOSIS

LYMPH NODE, "RIGHT COMMON," DISSECTION

- NO EVIDENCE OF MALIGNANCY (1/1)

LYMPH NODE, "RIGHT PERIAORTIC," DISSECTION

- NO EVIDENCE OF MALIGNANCY (1/1)

LYMPH NODE, "DISTAL COMMON," DISSECTION

- NO EVIDENCE OF MALIGNANCY (1/1)

LYMPH NODE, "RIGHT DISTAL PELVIS," DISSECTION

- NO EVIDENCE OF MALIGNANCY (2/2)

1CD-0-3
carcinoma, squamous cell 8070/3
Site: cervix, Nbs C53.9 lw 8/18/11

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis).

M.D.

Report Electronically Reviewed and Signed Out By *[Signature]* M.D.

Microscopic Description and Comment:

Microscopic examination substantiates the above cited diagnosis.

History:

The patient is a _____ year old woman with a history of cervical cancer. Operative procedure: _____, cervical biopsy, retroperitoneal removal right node and below.

Specimen(s) Received:

1 CERVIX, CERVICAL BIOPSY
1 RIGHT EXTERNAL LYMPH NODE

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

- C: RIGHT COMMON LYMPH NODE
- D: RIGHT PERIAORTIC LYMPH NODE
- E: DISTAL COMMON LYMPH NODE
- F: RIGHT DISTAL PELVIS LYMPH NODE

Gross Description

The specimens are received in six formalin-filled containers, each labeled with labeled "cervical biopsy" and contains an irregular gray-white piece of fat, measuring 1.1 x 0.9 x 0.7 cm in overall dimension. Inked and labeled A1. Jar 0.

The second container is labeled "right external lymph node" and contains an irregular fatty tissue fragment, containing lymph nodes, measuring 3.2 x 1.9 x 1 cm in overall dimensions. Two lymph nodes are dissected and submitted in entirety, labeled B1 and B2. Jar 0.

The third container is labeled "right common lymph node" and contains a single lymph node, with surrounding fat, measuring 2 x 1.4 x 0.8 cm. The specimen is bisected and submitted in its entirety, labeled C1. Jar 0.

The fourth container is labeled "right periaortic lymph node" and contains two fatty tissue fragments, one of which contains a single lymph node, aggregating to 3.5 x 3.2 x 0.4 cm. The lymph node is dissected and submitted in its entirety. Labeled D1. Jar 1.

The fifth container is labeled "distal common lymph node" and contains an irregular fatty tissue fragment containing a single lymph node, measuring 2.5 x 1.7 x 0.6 cm in overall dimensions. The lymph node is bisected and submitted in its entirety. Labeled E1. Jar 1.

The sixth container is labeled "right distal pelvis" and contains two firm, yellowish fatty tissue fragments, measuring 3.6 x 1.5 x 1.5 cm. The larger fragment is submitted labeled F1 to F3, and the smaller fragment, F4 and F5. Jar 0.

This Surgical Pathology report is available on-line on

The performance characteristics of all immunohistochemical tests used in this report (if any) were determined by the Diagnostic Immunohistochemistry Laboratory. The Clinical Laboratory Improvement Amendments of 1988 (CLIA '88) state that these tests rely on the use of "analyte specific reagents" and are subject to specific testing requirements by the US Food and Drug Administration. Such diagnostic tests may only be performed in a facility that is certified by the Health Care Financing Administration as a high complexity laboratory under CLIA '88. These tests have not been cleared or approved by the FDA prior to this use. Furthermore, federal rules concerning the marketing of analyte specific reagents require that the following disclaimer be attached to the report. This test has developed and its performance characteristics determined by the Diagnostic Immunohistochemistry Laboratory of Barnes-Jewish Hospital. It has not been cleared or approved by the U. S. Food and Drug Administration.

Source: NCI Genomic Data Commons file 90ef0bb9-b1e3-4c70-a044-b4e415db0b05 (TCGA-C5-A2LY.BA97051E-10A1-46D8-B5EF-D8163C5430D9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).